TCGA case TCGA-29-A5NZ — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1cb3d48-1415-408d-89d1-dfdcc5924963

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 1,088 days (3.0 years).

Diagnoses (9)
1. Papillary serous cystadenocarcinoma (the primary disease): ICD-O-3 morphology code: 8460/3; ICD-10 code: C48.1; Tissue or organ of origin: Specified parts of peritoneum; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 66.1 years (24,161 days); Year of diagnosis: 2011; FIGO stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,088 days (3.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 25 days; Days to treatment end: 151 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 396 days (1.1 years); Days to treatment end: 543 days (1.5 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 686 days (1.9 years); Days to treatment end: 817 days (2.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Paclitaxel; Days to treatment start: 893 days (2.4 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary serous cystadenocarcinoma). Age at diagnosis: 67.1 years (24,519 days); Days to diagnosis: 358 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 67.2 years (24,557 days); Days to diagnosis: 396 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 1 (Papillary serous cystadenocarcinoma). Age at diagnosis: 67.2 years (24,557 days); Days to diagnosis: 396 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 68.1 years (24,858 days); Days to diagnosis: 697 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
6. Recurrence of diagnosis 1 (Papillary serous cystadenocarcinoma). Age at diagnosis: 68.1 years (24,858 days); Days to diagnosis: 697 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
7. Progression of diagnosis 1 (Papillary serous cystadenocarcinoma). Age at diagnosis: 68.1 years (24,865 days); Days to diagnosis: 704 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
8. Progression of diagnosis 1 (Papillary serous cystadenocarcinoma). Age at diagnosis: 68.6 years (25,040 days); Days to diagnosis: 879 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
9. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 68.6 years (25,040 days); Days to diagnosis: 879 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (7 entries)
- Day 358 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 358 days.
- Day 396 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 396 days (1.1 years).
- Day 697 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 697 days (1.9 years).
- Day 704 (post initial treatment): Progression or recurrence: Yes; Days to progression: 704 days (1.9 years).
- Day 879 (post initial treatment): Progression or recurrence: Yes; Days to progression: 879 days (2.4 years).
- Days to follow up: 984 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 1,088 days (3.0 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-A5NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,040 mg.
  Slide TCGA-29-A5NZ-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-29-A5NZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Omentum; Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 6: Pharmaceutical therapy drug name: Gemzar; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,088 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,088 days; disease-free interval: event (new tumor event after initially disease-free), 358 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 358 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-A5NZ-01A-11D-A402-01): tumor purity 0.86, ploidy 3.58, whole-genome doublings 1.
